Somatic mutation profile of tumor specimen TARGET-30-PAINLN-01A (aliquot TARGET-30-PAINLN-01A-01W) from TARGET case TARGET-30-PAINLN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 3.8 years (1,404 days).
Specimen TARGET-30-PAINLN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 847e5e56-8702-4764-ad53-9abc27f232df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAINLN-10A (Blood Derived Normal), aliquot TARGET-30-PAINLN-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/257acd5f-04ac-42a4-91c1-6da3348c2a74

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3733T>A p.F1245I | Missense Mutation (SNP) | VAF 61/181 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281864720, CM113794, COSV66555887, COSV66558742; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201447364; called by muse, mutect2, varscan2
- ASZ1 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV52916970; called by muse, varscan2
- ATP6V1C2 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs765636133, COSV55365762; called by muse, mutect2, varscan2
- CATSPER1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV56409376; called by muse, mutect2, varscan2
- CELSR3 | c.9850G>C p.G3284R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV50852099, COSV51173267; called by muse, mutect2
- ERG28 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53164838; called by muse, mutect2, varscan2
- GAREM1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 109/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52516809; called by muse, mutect2, varscan2
- ORAI3 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.11); catalogued as COSV52689576, COSV52693367; called by muse, mutect2, varscan2
- PITPNM1 | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54162106; called by muse, mutect2, varscan2
- PLAC8L1 | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61014412, COSV61014705; called by muse, mutect2, varscan2
- PZP | c.3955G>A p.V1319I | Missense Mutation (SNP) | VAF 88/536 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54371895; called by muse, mutect2, varscan2
- TEAD4 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV63282728; called by muse, mutect2, varscan2
- TNC | c.5222G>A p.R1741Q | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.752); catalogued as rs149299073; called by muse, mutect2, varscan2
- TP63 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99288481; called by muse, mutect2
- UTP20 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs1565787551, COSV55386556; called by muse, mutect2, varscan2
- FMO1 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 30/670 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- COL27A1 | c.228T>C p.F76= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV61931419; called by muse, mutect2, varscan2
- GUCY2D | c.1329C>T p.P443= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1292562609, COSV54699386; called by muse, mutect2, varscan2
- OR52B2 | c.780C>A p.T260= | Silent (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- TWF1 | c.345C>T p.G115= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV57302242; called by muse, mutect2, varscan2
- VWF | c.3564G>A p.Q1188= | Silent (SNP) | VAF 55/607 reads (9%) | called by muse, mutect2
